Somatic mutation profile of tumor specimen TARGET-10-PATIKN-03A (aliquot TARGET-10-PATIKN-03A-01D) from TARGET case TARGET-10-PATIKN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (699 days).
Specimen TARGET-10-PATIKN-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47052df9-8def-4c2c-84bc-b99f9dd58bbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATIKN-10A (Blood Derived Normal), aliquot TARGET-10-PATIKN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/211179f6-0b78-4e21-a0aa-6a310b81558e

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60718422; called by muse, mutect2, varscan2
- LMX1A | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs559035208, COSV54224377; called by muse, mutect2, varscan2
- MUC5AC | c.10771G>A p.E3591K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1451732701; called by mutect2, varscan2
- ZNF71 | c.1300G>A p.G434S | Missense Mutation (SNP) | VAF 84/149 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs759686490, COSV60150153; called by muse, mutect2, varscan2
- MUC5AC | c.12070G>A p.E4024K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- PTEN | c.701_708del p.R234Qfs*6 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by pindel, varscan2*
- OR6C70 | c.843G>A p.P281= | Silent (SNP) | VAF 53/135 reads (39%) | catalogued as rs781423925; called by muse, mutect2, varscan2
- SPTBN4 | c.4635C>T p.N1545= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs776501445; called by muse, mutect2, varscan2
